Somatic mutation profile of tumor specimen TCGA-2G-AAFJ-01A (aliquot TCGA-2G-AAFJ-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAFJ, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Teratoma, malignant, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 23.0 years (8,415 days).
Specimen TCGA-2G-AAFJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7347310a-10e6-47f1-aecb-4877e22e8ae6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAFJ-10A (Blood Derived Normal), aliquot TCGA-2G-AAFJ-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc339b20-09bf-4b02-8ac7-0fb8767722d9

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Intron 2, Nonsense Mutation 2, Splice Site 1, RNA 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW5 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs140846203; called by muse, mutect2, varscan2
- MLH3 | c.3381T>C p.D1127= | Splice Region (SNP) | VAF 22/105 reads (21%) | catalogued as COSV53159764; called by muse, mutect2, varscan2
- YARS2 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs925095566; called by muse, mutect2, varscan2
- ZFR2 | c.1434C>G p.N478K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1445885027; called by muse, mutect2
- CCDC40 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | called by muse, mutect2, varscan2
- ENPP3 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAM193B | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GNAS | c.880C>G p.Q294E | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NAA15 | c.774G>T p.W258C | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); called by muse, mutect2
- OBSCN | c.20158T>A p.W6720R | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RRAGA | c.790_798del p.D264_F266del | In Frame Del (DEL) | VAF 52/101 reads (51%) | called by mutect2, pindel, varscan2
- SHISA6 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOS1 | c.2973T>A p.F991L | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- SRCAP | c.7147A>T p.K2383* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- SYCE2 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TNPO1 | c.627T>A p.F209L | Missense Mutation (SNP) | VAF 74/90 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- YWHAQ | c.679-1G>C p.X227_splice | Splice Site (SNP) | VAF 12/414 reads (3%) | called by muse, mutect2
- ZNF12 | c.1935G>A p.M645I (on ENST00000405858 / NM_016265.4; = p.M607I on NM_006956.3) | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.942); called by muse, mutect2
- GNPAT | c.1167A>T p.I389= | Silent (SNP) | VAF 36/135 reads (27%) | called by muse, mutect2, varscan2
- PKD2L1 | c.1815G>A p.V605= | Silent (SNP) | VAF 56/206 reads (27%) | called by muse, mutect2, varscan2
- TUSC3 | c.471A>G p.K157= | Silent (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1448-34G>A | Intron (SNP) | VAF 56/156 reads (36%) | catalogued as rs1369357988; called by muse, mutect2, varscan2
- PRMT7 | c.1576-45G>A | Intron (SNP) | VAF 4/38 reads (11%) | catalogued as rs1255837892; called by muse, mutect2
- SSPOP | n.11267C>A | RNA (SNP) | VAF 15/132 reads (11%) | catalogued as rs369846479; called by muse, mutect2, varscan2
